Somatic mutation profile of tumor specimen MP2PRT-PAVJUE-TMP1-A (aliquot MP2PRT-PAVJUE-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVJUE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,618 days).
Specimen MP2PRT-PAVJUE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08102eda-4459-4583-a8d3-ea7099f05023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJUE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJUE-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87c325c1-d08e-4fd4-b3e4-f79f8990c17a

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 12, Nonsense Mutation 5, Intron 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 42/502 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADCY10 | c.601A>G p.M201V | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1186138810; called by muse, mutect2, varscan2
- ANAPC4 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as rs756665756; called by muse, mutect2
- ATG2B | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 16/564 reads (3%) | catalogued as COSV100737603; called by muse, mutect2
- CFAP47 | c.5515G>C p.D1839H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV100545003; called by muse, mutect2, varscan2
- CFAP69 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100290476; called by muse, mutect2, varscan2
- CFHR5 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV56828295; called by muse, mutect2
- CNTN2 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 81/444 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs571201763; called by muse, mutect2, varscan2
- DLL3 | c.222G>C p.E74D | Missense Mutation (SNP) | VAF 171/698 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV99219478; called by muse, mutect2, varscan2
- DSCAM | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 93/570 reads (16%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.503); catalogued as rs1374375102, COSV68650125; called by muse, mutect2, varscan2
- FGD6 | c.3641C>T p.S1214L | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs751711117; called by muse, mutect2
- LMAN1L | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs1301778714; called by muse, mutect2
- MAP2 | c.2252C>G p.P751R | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs921628169, COSV52286975; called by muse, mutect2, varscan2
- NRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV65731978; called by mutect2, varscan2
- PCLO | c.13982C>G p.S4661C | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100429088; called by muse, mutect2, varscan2
- PDE1A | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs146808624; called by muse, mutect2, varscan2
- PLCG1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 24/716 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.084); catalogued as COSV54823181; called by muse, mutect2
- SATL1 | c.261G>C p.M87I (on ENST00000395409; = p.M274I on NM_001012980.2) | Missense Mutation (SNP) | VAF 161/219 reads (74%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60576796; called by muse, mutect2, varscan2
- SPATA31D3 | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as rs1300757062; called by muse, mutect2, varscan2
- ZNF583 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV52402195; called by muse, mutect2
- ZNF730 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV74168097; called by muse, mutect2
- AKAP4 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARID2 | c.2418G>T p.Q806H | Missense Mutation (SNP) | VAF 89/421 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARIH1 | c.1236G>C p.Q412H | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); called by muse, mutect2
- C14orf39 | c.1709C>G p.S570C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CABP1 | c.1084G>C p.E362Q (on ENST00000316803 / NM_001033677.1; = p.E159Q on NM_004276.5) | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPZA3 | c.382T>G p.Y128D | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CATSPER2 | c.531G>C p.W177C | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CCNB3 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- CSNK1E | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 32/401 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2
- DDX60L | c.527C>G p.S176* | Nonsense Mutation (SNP) | VAF 53/256 reads (21%) | called by muse, mutect2, varscan2
- FZD3 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 23/524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FZD3 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- GAK | c.2410G>C p.E804Q | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPATCH8 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2
- GYS2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 43/272 reads (16%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 15/297 reads (5%) | called by muse, mutect2
- MAP2 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 81/404 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- MYOM2 | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- OR10A6 | c.639G>C p.L213F | Missense Mutation (SNP) | VAF 55/473 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOGL | c.3257C>G p.S1086* (on ENST00000547103; = p.S1077* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 63/226 reads (28%) | called by muse, mutect2, varscan2
- P4HTM | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 23/508 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- PPP6R2 | c.1743C>G p.F581L (on ENST00000216061 / NM_001365836.1; = p.F554L on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/338 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.326); called by muse, varscan2
- SNRPA1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2
- UQCC3 | c.277_281delinsTCTT p.P93Sfs*2 | Frame Shift Del (DEL) | VAF 58/346 reads (17%) | called by pindel, varscan2*
- XRCC5 | c.682_683insCTCCC p.S228Tfs*6 | Frame Shift Ins (INS) | VAF 72/158 reads (46%) | called by mutect2, pindel*, varscan2*
- ZNF596 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF596 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- C11orf87 | c.582G>A p.V194= | Silent (SNP) | VAF 71/207 reads (34%) | called by muse, mutect2, varscan2
- GLS | c.204C>T p.L68= | Silent (SNP) | VAF 192/776 reads (25%) | called by muse, mutect2, varscan2
- MLXIPL | c.1944G>A p.E648= | Silent (SNP) | VAF 11/300 reads (4%) | called by muse, mutect2
- OR4D11 | c.435C>T p.I145= | Silent (SNP) | VAF 23/404 reads (6%) | called by muse, mutect2
- PAQR7 | c.1040G>A p.*347= | Silent (SNP) | VAF 50/184 reads (27%) | called by muse, mutect2, varscan2
- SIPA1 | c.813G>T p.R271= | Silent (SNP) | VAF 80/417 reads (19%) | called by muse, mutect2, varscan2
- SLC6A1 | c.162C>G p.L54= | Silent (SNP) | VAF 89/330 reads (27%) | catalogued as rs752627902; called by muse, mutect2, varscan2
- SRF | c.1365C>A p.P455= | Silent (SNP) | VAF 103/310 reads (33%) | called by muse, mutect2, varscan2
- SRY | c.267G>A p.E89= | Silent (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- TAAR2 | c.801G>A p.V267= (on ENST00000367931 / NM_001033080.1; = p.V222= on NM_014626.3) | Silent (SNP) | VAF 7/204 reads (3%) | catalogued as COSV51579289; called by muse, mutect2
- TMED9 | c.138G>A p.E46= | Silent (SNP) | VAF 113/474 reads (24%) | catalogued as rs774814357; called by muse, mutect2, varscan2
- TOLLIP | c.462G>C p.L154= | Silent (SNP) | VAF 45/505 reads (9%) | called by muse, mutect2
- IKBIP | c.297+7714G>A | Intron (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- NPSR1 | c.1026-160G>C | Intron (SNP) | VAF 68/302 reads (23%) | called by muse, mutect2, varscan2
